Somatic mutation profile of tumor specimen 0DWYWI from CCDI case PBCNZI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.5 years (2,003 days).
Specimen 0DWYWI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23651e05-58cd-4db5-b660-7deed1f9dfe5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be18cd04-9154-4ae1-b731-2c64e2b101a4

The open-access MAF lists 43 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Intron 4, 5'UTR 2, Nonsense Mutation 1, RNA 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AJM1 | c.2834G>A p.R945H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56031981; called by muse, mutect2, varscan2
- APOC2 | c.143G>T p.W48L | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1168257297; called by muse, mutect2, varscan2
- C1QB | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544508692, CM116184, COSV59245564; called by muse, mutect2, varscan2
- GBP1 | c.1309G>T p.V437F | Missense Mutation (SNP) | VAF 117/306 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs574206530; called by muse, mutect2, varscan2
- GIMAP6 | c.502C>A p.L168M | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61032768; called by muse, mutect2, varscan2
- KCNMA1 | c.3196G>A p.G1066R (on ENST00000286628 / NM_001161352.2; = p.G1008R on NM_002247.4) | Missense Mutation (SNP) | VAF 163/352 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371351993; called by muse, mutect2, varscan2
- MUC16 | c.37983C>A p.F12661L | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.071); catalogued as rs1198509129; called by muse, mutect2, varscan2
- ZMYM4 | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 29/383 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs774572980, COSV100109850; called by muse, mutect2
- AHSA1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMBN | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 159/390 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ATAD2 | c.2624C>G p.A875G | Missense Mutation (SNP) | VAF 142/474 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DYNC2H1 | c.975C>A p.D325E | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- GJA10 | c.1031C>A p.A344D | Missense Mutation (SNP) | VAF 55/231 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- LIPN | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 165/392 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- MED19 | c.667-3C>A | Splice Region (SNP) | VAF 47/140 reads (34%) | called by muse, mutect2, varscan2
- MRPL9 | c.397T>G p.S133A | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- OR10J3 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 100/375 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- REV3L | c.8440A>T p.K2814* | Nonsense Mutation (SNP) | VAF 60/575 reads (10%) | called by muse, mutect2
- RNF180 | c.54T>A p.S18R | Missense Mutation (SNP) | VAF 174/385 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SHANK3 | c.5134A>T p.M1712L | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SLC35G1 | c.817T>G p.L273V (on ENST00000427197 / NM_001134658.3; = p.L272V on NM_153226.4) | Missense Mutation (SNP) | VAF 12/367 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.082); called by muse, mutect2
- SNORC | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 5/128 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.01); called by muse, mutect2
- SRCIN1 | c.2740G>A p.G914R (on ENST00000621492; = p.G880R on NM_025248.3) | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D31 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS11F | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 134/377 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- ZFC3H1 | c.3652A>T p.I1218F | Missense Mutation (SNP) | VAF 151/577 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- DSG3 | c.2178A>G p.G726= | Silent (SNP) | VAF 124/516 reads (24%) | called by muse, varscan2
- FHOD1 | c.777G>T p.L259= | Silent (SNP) | VAF 20/300 reads (7%) | called by muse, mutect2
- FLNC | c.4962G>T p.L1654= | Silent (SNP) | VAF 18/233 reads (8%) | catalogued as COSV100367794; called by muse, mutect2
- FOXG1 | c.810G>T p.T270= | Silent (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- GGCX | c.432G>T p.L144= | Silent (SNP) | VAF 111/270 reads (41%) | catalogued as COSV52088357; called by muse, mutect2, varscan2
- IL4R | c.1980G>A p.E660= | Silent (SNP) | VAF 55/149 reads (37%) | called by muse, mutect2, varscan2
- KIF26B | c.4581T>C p.H1527= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV100831503; called by muse, mutect2, varscan2
- STYXL2 | c.1851G>T p.S617= | Silent (SNP) | VAF 43/140 reads (31%) | catalogued as COSV54811049; called by muse, mutect2, varscan2
- ZNF7 | c.729C>T p.N243= | Silent (SNP) | VAF 65/393 reads (17%) | catalogued as rs978195061; called by muse, mutect2, varscan2
- BSPRY | c.*57A>G | 3'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- HDDC2 | c.310-27A>G | Intron (SNP) | VAF 50/182 reads (27%) | called by muse, mutect2, varscan2
- IL5 | c.-4A>G | 5'UTR (SNP) | VAF 12/209 reads (6%) | called by muse, mutect2
- IL5 | c.-5G>T | 5'UTR (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- ILF3 | c.1180+48G>C | Intron (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- SH3GL3 | c.839-6625G>T | Intron (SNP) | VAF 88/189 reads (47%) | called by muse, mutect2, varscan2
- TMBIM7P | n.553C>T | RNA (SNP) | VAF 79/316 reads (25%) | called by muse, mutect2, varscan2
- TREM2 | c.483-14C>T | Intron (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
